Somatic mutation profile of tumor specimen TCGA-ZM-AA0E-01A (aliquot TCGA-ZM-AA0E-01A-12D-A435-10) from TCGA case TCGA-ZM-AA0E, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 39.0 years (14,255 days).
Specimen TCGA-ZM-AA0E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0425afd-a323-49f9-8ac4-a475bb49768f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZM-AA0E-10A (Blood Derived Normal), aliquot TCGA-ZM-AA0E-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10645b89-16f6-4927-81fb-90753d15dbc0

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGKV3D-11 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- LRRC53 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.747); called by muse, mutect2
- RPS5 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TENM4 | c.38C>G p.T13S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.6); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TLR2 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- ZNF217 | c.1465C>T p.H489Y | Missense Mutation (SNP) | VAF 39/472 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNMT1 | c.240T>C p.A80= | Silent (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- TMX2 | c.324G>A p.L108= | Silent (SNP) | VAF 18/110 reads (16%) | called by muse, mutect2, varscan2
